Somatic mutation profile of tumor specimen TCGA-AR-A0TZ-01A (aliquot TCGA-AR-A0TZ-01A-12D-A099-09) from TCGA case TCGA-AR-A0TZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.0 years (15,720 days).
Specimen TCGA-AR-A0TZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323a9929-2fad-4158-93b6-310cf78fe6cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TZ-10A (Blood Derived Normal), aliquot TCGA-AR-A0TZ-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82a5e82b-c360-48ab-966f-d3c8a2d29b5c

The open-access MAF lists 56 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 41, Silent 9, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF4 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786205680, CM152551, COSV99534537; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | catalogued as COSV99225184; called by muse, mutect2, varscan2
- ATP1B4 | c.772C>T p.R258C (on ENST00000218008 / NM_001142447.3; = p.R254C on NM_012069.5) | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs149447498, COSV54312900; called by muse, mutect2, varscan2
- BOP1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs782512248, COSV56639614; called by muse, mutect2
- BSN | c.9607C>T p.R3203C | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs144614681; called by muse, mutect2, varscan2
- CEP70 | c.1644C>G p.D548E | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99388792; called by muse, mutect2, varscan2
- CIT | c.3728G>A p.R1243Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs1380018726, COSV99948290; called by muse, mutect2, varscan2
- CLINT1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764235760, COSV99753388; called by muse, mutect2, varscan2
- CPT1A | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99680544; called by muse, mutect2, varscan2
- CSRNP3 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100085050; called by muse, mutect2, varscan2
- CTR9 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100797248; called by muse, mutect2, varscan2
- DCDC1 | c.3987G>A p.M1329I (on ENST00000597505 / NM_001367979.1; = p.M436I on NM_020869.3) | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV100337809; called by muse, mutect2, varscan2
- DYNC1I2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV99783603; called by muse, mutect2, varscan2
- EHD1 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs1216574356, COSV100276822, COSV57735716; called by muse, mutect2, varscan2
- EMB | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100296593, COSV57484510; called by muse, mutect2, varscan2
- FBF1 | c.1132C>T p.P378S (on ENST00000586717; = p.P392S on NM_001319193.1) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as COSV100044706; called by muse, mutect2
- FCF1 | c.455A>G p.H152R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs762739932, COSV100356653; called by muse, mutect2, varscan2
- HCFC1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100128357; called by muse, mutect2, varscan2
- HGF | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99735483; called by muse, mutect2, varscan2
- HIPK2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61226590; called by muse, mutect2, varscan2
- KIAA2026 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV101198832; called by muse, mutect2, varscan2
- KMT2C | c.13496A>G p.K4499R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100066166; called by muse, mutect2, varscan2
- LGALS12 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99736817; called by muse, mutect2, varscan2
- LIAS | c.757+1G>T p.X253_splice (on ENST00000261434 / NM_001363700.2; = p.X356_splice on NM_006859.4) | Splice Site (SNP) | VAF 59/152 reads (39%) | catalogued as rs771232207, COSV99787538; called by muse, mutect2, varscan2
- LPO | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757850644, COSV51860612, COSV99229266; called by muse, mutect2, varscan2
- MBD5 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV101289917; called by muse, mutect2, varscan2
- MED23 | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644738; called by muse, mutect2, varscan2
- NAA60 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.56); catalogued as COSV100692701; called by muse, mutect2, varscan2
- NPY1R | c.426A>G p.I142M | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99648448; called by muse, mutect2, varscan2
- PCSK2 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99358600; called by muse, mutect2, varscan2
- PRR14 | c.1727C>T p.T576I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs748607303, COSV99788257; called by muse, mutect2, varscan2
- SCFD2 | c.877A>T p.I293F | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV101189226; called by muse, mutect2, varscan2
- SDR16C5 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV100373771, COSV58126701; called by muse, mutect2, varscan2
- SIPA1L1 | c.2060C>G p.S687C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100665087; called by muse, mutect2, varscan2
- SLC1A7 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs201010691, COSV65195411; called by muse, mutect2, varscan2
- SNURF | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.872); catalogued as COSV100577854; called by muse, mutect2, varscan2
- SRSF11 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100917791; called by muse, mutect2, varscan2
- STC1 | c.261+1G>A p.X87_splice | Splice Site (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99282304; called by muse, mutect2, varscan2
- STON2 | c.1823A>T p.D608V (on ENST00000649389 / NM_001366849.2; = p.D551V on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99964362; called by muse, mutect2, varscan2
- TFAP2B | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53825294, COSV99540314; called by muse, mutect2, varscan2
- TRAPPC9 | c.2401C>T p.Q801* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV101226593; called by muse, mutect2, varscan2
- ZEB1 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1178786891, COSV58054472; called by muse, mutect2, varscan2
- ZKSCAN7 | c.2048G>T p.R683I | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56272735, COSV56273453; called by muse, mutect2, varscan2
- ZNF804B | c.3325C>T p.H1109Y | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60815291; called by muse, mutect2, varscan2
- MRPL46 | c.730del p.S244Pfs*21 | Frame Shift Del (DEL) | VAF 60/150 reads (40%) | called by mutect2, pindel, varscan2
- PIGW | c.266T>G p.F89C | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- B4GALT4 | c.789C>G p.L263= | Silent (SNP) | VAF 54/73 reads (74%) | catalogued as COSV100785751; called by muse, mutect2, varscan2
- H2AC11 | c.132C>T p.V44= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs1275748750, COSV100345588; called by muse, mutect2, varscan2
- HPS1 | c.222G>A p.T74= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1016660490; called by muse, mutect2
- MAGEA8 | c.792G>A p.A264= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs376840959, COSV54063614; called by muse, mutect2, varscan2
- NOX5 | c.1107G>A p.P369= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs1484299977, COSV52996370; called by muse, mutect2, varscan2
- PCNX2 | c.6201G>A p.V2067= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99265941; called by muse, mutect2, varscan2
- RELN | c.7641G>A p.A2547= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as rs749089939, COSV58983944; ClinVar: likely benign; called by muse, mutect2, varscan2
- STRA6 | c.228C>G p.L76= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100120783; called by muse, mutect2, varscan2
- ZP4 | c.888C>T p.I296= | Silent (SNP) | VAF 90/232 reads (39%) | catalogued as COSV63912698; called by muse, mutect2, varscan2
